Somatic mutation profile of tumor specimen TCGA-L5-A8NW-01A (aliquot TCGA-L5-A8NW-01A-11D-A37C-09) from TCGA case TCGA-L5-A8NW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: GX; Age at diagnosis: 55.3 years (20,194 days).
Specimen TCGA-L5-A8NW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7597f618-55be-44b3-a52e-2fb71233830f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NW-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NW-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc625e95-ebf7-4e1f-a8ca-9534e61fc80a

The open-access MAF lists 172 somatic variants for this specimen: 126 protein-altering or splice-affecting, 43 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 43, Nonsense Mutation 5, Frame Shift Del 5, Frame Shift Ins 4, RNA 2, Splice Region 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs587782943, COSV57310950; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 17/32 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.3322G>A p.A1108T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs746089621, COSV59387039; called by muse, mutect2, varscan2
- ADAMTS3 | c.300A>C p.Q100H | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs751923787; called by muse, mutect2, varscan2
- AHCY | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.118); catalogued as rs377090568; called by muse, mutect2, varscan2
- ANKRD50 | c.2641C>T p.R881* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs758221035, COSV72385818; called by muse, mutect2, varscan2
- BRINP1 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as rs764358377, COSV99775387; called by muse, mutect2, varscan2
- CACNA2D4 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs772210135, COSV99765371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMTA1 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57881388; called by muse, mutect2, varscan2
- CDH9 | c.2063T>G p.L688R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV50251341; called by muse, mutect2, varscan2
- CLK3 | c.748C>T p.R250W (on ENST00000395066 / NM_001130028.1; = p.R102W on NM_003992.4) | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as rs747353105; called by muse, mutect2, varscan2
- CSPP1 | c.1806-2A>G p.X602_splice (on ENST00000676605; = p.X561_splice on NM_024790.6) | Splice Site (SNP) | VAF 30/89 reads (34%) | catalogued as COSV51584221; called by muse, mutect2, varscan2
- CWC22 | c.2608A>G p.R870G | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs767248587, COSV55428280; called by muse, mutect2, varscan2
- DOCK2 | c.5087G>A p.R1696Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs371229305, COSV56977328; called by muse, mutect2, varscan2
- EPHA3 | c.1331A>G p.K444R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1473800664; called by muse, mutect2, varscan2
- FASN | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.451); catalogued as rs41283367, COSV60751989; called by muse, varscan2
- FOXG1 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV57398665; called by muse, mutect2, varscan2
- GNE | c.326G>A p.G109E (on ENST00000396594 / NM_001128227.3; = p.G78E on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs886043490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR12 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs758632134, COSV67343989; called by muse, mutect2, varscan2
- GPR15 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs1201835927; called by muse, mutect2, varscan2
- GTF3C3 | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs756830407; called by mutect2, varscan2
- H2AC16 | c.20A>T p.Q7L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV58901840; called by muse, mutect2, varscan2
- IFRD2 | c.376dup p.D126Gfs*5 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | catalogued as rs782027045; called by mutect2, varscan2
- LRP1B | c.8969A>G p.K2990R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1027838580; called by muse, mutect2, varscan2
- LRRK2 | c.7546G>T p.E2516* | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | catalogued as COSV100110283; called by muse, mutect2, varscan2
- LRRTM1 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as COSV54439358; called by muse, mutect2, varscan2
- MAG | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.45); PolyPhen benign (0.053); catalogued as rs1414875485, COSV62699226; called by muse, mutect2, varscan2
- MAGEA1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 52/70 reads (74%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs782683172; called by muse, mutect2, varscan2
- MDH1B | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs932420771; called by muse, mutect2, varscan2
- MIDEAS | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs772631943, COSV54096790; called by muse, varscan2
- NBEA | c.7399C>A p.L2467I | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59757388; called by muse, mutect2, varscan2
- NDST1 | c.1636C>G p.L546V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.795); catalogued as rs1401648515; called by muse, mutect2, varscan2
- NFATC1 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs748548145; called by muse, mutect2, varscan2
- NLRP8 | c.1208G>T p.C403F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52589485; called by muse, mutect2, varscan2
- NSUN5 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs563841683; called by muse, mutect2, varscan2
- OR6C68 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.063); catalogued as rs758817890; called by muse, mutect2, varscan2
- PCDHB4 | c.1677C>A p.F559L | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV52022887; called by muse, mutect2, varscan2
- RBM4 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs577949918, COSV59520455; called by muse, mutect2, varscan2
- RTP2 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.343); catalogued as COSV104420237; called by muse, mutect2, varscan2
- SLC12A7 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs776940312; called by muse, mutect2, varscan2
- SLC1A2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374504230; called by muse, mutect2, varscan2
- SLC39A6 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs749354395, COSV52368575; called by muse, mutect2, varscan2
- SMARCA4 | c.3202G>A p.G1068S | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs765857427, COSV60810653; called by muse, mutect2, varscan2
- SPECC1 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs764238558, COSV54960010; called by muse, mutect2, varscan2
- ST8SIA3 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | PolyPhen benign (0.07); catalogued as rs767322017; called by muse, mutect2, varscan2
- TACC2 | c.4774G>A p.D1592N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV57775760; called by muse, mutect2
- TTC37 | c.3853A>G p.K1285E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs148969228; called by muse, mutect2, varscan2
- UQCC1 | c.842A>C p.K281T | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.338); catalogued as COSV100568748, COSV62902004; called by muse, mutect2, varscan2
- ZNF420 | c.729A>C p.K243N | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs775585428; called by muse, mutect2, varscan2
- ZNF800 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs767881955; called by muse, mutect2, varscan2
- ZNRF4 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.015); catalogued as rs899059482, COSV55774340; called by muse, mutect2, varscan2
- ABCA5 | c.913dup p.L305Pfs*18 | Frame Shift Ins (INS) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- ABCB11 | c.279C>A p.Y93* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- ACKR1 | c.946T>G p.L316V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ASXL2 | c.431G>T p.C144F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- B4GALNT1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- BANK1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BAZ2B | c.4984G>A p.E1662K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- BMPR2 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C19orf57 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- CFAP61 | c.1890G>T p.K630N | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHST9 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CIP2A | c.2706T>A p.N902K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLDN17 | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- COL12A1 | c.7579T>C p.Y2527H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CPNE4 | c.1171A>C p.I391L | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- CRISPLD1 | c.334T>A p.L112M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- EDEM3 | c.1382_1385del p.F461Sfs*23 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by pindel, varscan2
- EIF3A | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EPB41L3 | c.2420A>C p.K807T | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- EPHA6 | c.1948G>A p.V650I (on ENST00000389672 / NM_001080448.3; = p.V42I on NM_173655.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ERAP2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- FGA | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBE1 | c.1651T>G p.F551V | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GMDS | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GPRIN1 | c.2741G>T p.S914I | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2
- GUSB | c.1860C>A p.F620L | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- HTRA3 | c.1135T>A p.F379I | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- IRGQ | c.1109G>A p.R370K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRX5 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- JADE2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KMT2D | c.9919G>A p.A3307T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KMT2E | c.2363A>T p.K788M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC8D | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- MALSU1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MAML2 | c.2042G>C p.R681T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MGAM | c.2689T>G p.L897V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- MYO16 | c.2607del p.K869Nfs*6 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- MYOM2 | c.3418G>A p.V1140I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR1L1 | c.1057T>G p.L353V (on ENST00000373686; = p.L303V on NM_001005236.3) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- OR2A42 | c.316T>A p.F106I | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- OR5T1 | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1454C>T p.T485I (on ENST00000259318 / NM_001136562.3; = p.T716I on NM_007203.5) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB12 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- PCDHB15 | c.1829C>A p.T610K | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PCYT2 | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- PDZRN3 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PGBD1 | c.1566G>T p.L522F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PHF7 | c.1028G>A p.W343* | Nonsense Mutation (SNP) | VAF 27/38 reads (71%) | called by muse, mutect2, varscan2
- PLEKHO2 | c.938del p.P313Hfs*9 | Frame Shift Del (DEL) | VAF 25/48 reads (52%) | called by mutect2, pindel, varscan2
- PRAMEF4 | c.125T>G p.F42C | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM9 | c.1382A>T p.K461I | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PTCHD3 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- PTPRR | c.181dup p.I61Nfs*5 | Frame Shift Ins (INS) | VAF 19/85 reads (22%) | called by mutect2, pindel, varscan2
- RANBP3L | c.267A>T p.G89= | Splice Region (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- RIMS1 | c.3266T>G p.F1089C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ROBO2 | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RTL3 | c.494A>T p.E165V | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RUFY4 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SACS | c.2645A>C p.K882T | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SASS6 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.2083T>C p.S695P | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- TCF4 | c.507_510del p.T170Rfs*63 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | called by mutect2, pindel, varscan2
- TLR2 | c.1047dup p.L350Sfs*20 | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- TLR6 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TMBIM6 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM87A | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPC4 | c.1496A>G p.N499S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- TYMP | c.240del p.R81Gfs*11 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | called by mutect2, pindel, varscan2
- ZFAND5 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ZNF155 | c.1588C>T p.L530F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF408 | c.1149C>G p.C383W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF420 | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF607 | c.920A>C p.K307T | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF721 | c.914C>A p.S305Y (on ENST00000338977; = p.S317Y on NM_133474.4) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZSCAN9 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ADGRB3 | c.1576A>C p.R526= | Silent (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- ALG6 | c.198G>A p.Q66= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54766272; called by muse, mutect2, varscan2
- ARMCX2 | c.930C>A p.G310= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV57529587; called by muse, mutect2, varscan2
- CCDC127 | c.39G>A p.R13= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- CFHR3 | c.483T>A p.S161= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs1323253629; called by muse, mutect2
- CSNK1G3 | c.1335C>T p.R445= | Silent (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- DMD | c.11011A>C p.R3671= | Silent (SNP) | VAF 15/19 reads (79%) | called by muse, mutect2, varscan2
- ENTPD2 | c.801G>A p.P267= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as rs371567979; called by muse, mutect2, varscan2
- FBN2 | c.8589C>G p.L2863= | Silent (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- FOLH1 | c.1803T>A p.A601= | Silent (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- GPR4 | c.84C>T p.I28= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs955073823, COSV59917726; called by muse, mutect2, varscan2
- GRIN1 | c.1563C>T p.N521= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs1327789874; called by muse, mutect2, varscan2
- H4C2 | c.12C>T p.R4= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs569686893; called by muse, mutect2
- HDX | c.1566A>T p.A522= | Silent (SNP) | VAF 34/50 reads (68%) | called by muse, mutect2, varscan2
- HPS3 | c.1167C>T p.N389= | Silent (SNP) | VAF 63/106 reads (59%) | called by muse, mutect2, varscan2
- HSPG2 | c.8982C>T p.A2994= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs143921375; called by muse, mutect2, varscan2
- LRRIQ4 | c.912C>T p.N304= | Silent (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- MS4A10 | c.696C>T p.G232= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs767824991, COSV57633217; called by mutect2, varscan2
- MSX1 | c.606C>T p.R202= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV101235685; called by muse, mutect2, varscan2
- MYOM3 | c.1911C>T p.S637= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1277262962; called by muse, mutect2, varscan2
- MYORG | c.1224C>T p.R408= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1397288809; called by muse, mutect2
- NKX2-2 | c.474C>T p.R158= | Silent (SNP) | VAF 68/144 reads (47%) | catalogued as rs1568636857, COSV65820353; called by muse, mutect2, varscan2
- NLRP11 | c.1803C>T p.I601= | Silent (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- NRP1 | c.2457C>T p.N819= | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- OR5D14 | c.612C>T p.F204= | Silent (SNP) | VAF 89/149 reads (60%) | catalogued as rs375849432; called by muse, mutect2, varscan2
- PABPC4 | c.1737C>T p.I579= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs868182270; called by muse, mutect2, varscan2
- PCDHA3 | c.2046G>A p.A682= | Silent (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- PDE3A | c.201G>A p.A67= | Silent (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- PEG3 | c.4578T>C p.T1526= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV55626937, COSV55641370; called by muse, mutect2, varscan2
- PELI3 | c.249G>T p.G83= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV57857181; called by muse, mutect2, varscan2
- PLOD3 | c.2184A>T p.T728= | Silent (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- PTPRS | c.2316G>A p.P772= | Silent (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2, varscan2
- PWWP2A | c.315C>T p.A105= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs1405296099; called by muse, mutect2
- SIGLEC14 | c.879C>A p.L293= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- TCTN2 | c.717C>T p.S239= | Silent (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- TIGD6 | c.216C>T p.S72= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs764459788; called by muse, mutect2, varscan2
- TINAGL1 | c.532C>T p.L178= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- TLN1 | c.3237A>G p.L1079= | Silent (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- TMEM79 | c.708G>C p.L236= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV55295228; called by muse, mutect2, varscan2
- ZNF420 | c.474A>G p.Q158= | Silent (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
- ZNF625 | c.1092G>A p.S364= | Silent (SNP) | VAF 49/77 reads (64%) | catalogued as rs115447016; called by muse, mutect2, varscan2
- ZSCAN1 | c.390G>A p.S130= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs143428215, COSV99992196; called by muse, mutect2, varscan2
- ZSCAN1 | c.1215C>T p.H405= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs776520299; called by muse, mutect2, varscan2
- CNTROB | c.2513+23G>A | Intron (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- MIR920 | n.39A>G | RNA (SNP) | VAF 8/21 reads (38%) | catalogued as COSV101290064; called by muse, mutect2, varscan2
- SNORD116-13 | n.75T>A | RNA (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
